Gene-level copy-number profile of tumor specimen MP2PRT-PAVUIG-TMP1-A from MP2PRT case MP2PRT-PAVUIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,156 days).
Specimen MP2PRT-PAVUIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cee1306c-ae84-4736-83bd-2a9cdac8a3ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVUIG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,883 have no estimate.
https://portal.gdc.cancer.gov/files/c60aeec9-b96e-428b-b017-b2bb598ab90f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 3,339; copy number 2: 55,375; copy number 3: 8.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A.
- chr7:142,749,468–142,753,076, 1 gene (within-gene range 0–1): PRSS1.
- chr7:142,760,415–142,779,537, 2 genes (within-gene range 0–1): PRSS3P1, WBP1LP1.
- chr7:142,796,365–142,796,610, 2 genes (within-gene range 0–1): TRBJ2-1, TRBJ2-2.
- chr14:22,415,362–22,465,787, 10 genes (within-gene range 0–2): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 483. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
